Gene-level copy-number profile of tumor specimen TCGA-50-5049-01A from TCGA case TCGA-50-5049, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 70.0 years (25,577 days).
Specimen TCGA-50-5049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.d4c73143-a434-4f22-87ee-ea2402279f25.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-50-5049-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a165e229-acb3-4ea4-9f18-08ab4caf9767

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 9,064; copy number 2: 16,273; copy number 3: 21,575; copy number 4: 9,427; copy number 5: 1,797; copy number 6: 1,219; copy number 7: 23; copy number 8: 249; copy number 9: 7; copy number 10: 112; copy number 11: 2; copy number 12: 2; copy number 16: 17; copy number 18: 5; copy number 19: 1; copy number 20: 1; copy number 64: 6; copy number 70: 10; copy number 125: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-50-5049-01A-01D-1624-01): tumor purity 0.26, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 464 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:138,725,211–140,205,326, 23 genes, copy number 12–70 (within-gene range 3–70): CCDC28A-AS1, CCDC28A, ECT2L, ACKR4P1, AL121834.1, REPS1, ABRACL, HECA, AL031772.1, AL158850.1, TXLNB, AL592429.2, AL592429.1, CITED2, LINC01625, ATP5PBP6, AL390205.1, FILNC1, AL050338.1, AL050338.2, AL357146.1, RNA5SP220, MIR3668.
- chr6:164,791,288–164,832,114, 2 genes, copy number 11: AL450345.2, AL450345.1.
- chr8:85,833,377–86,343,429, 11 genes, copy number 8 (within-gene range 4–8): AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1.
- chr8:93,213,302–93,700,433, 1 gene, copy number 8 (within-gene range 4–8): LINC00535.
- chr8:93,441,277–99,895,121, 131 genes, copy number 8 (broad region; genes not listed).
- chr8:100,004,583–100,004,649, 1 gene, copy number 8: SNORD77B.
- chr8:100,683,488–103,501,895, 87 genes, copy number 8 (broad region; genes not listed).
- chr8:103,559,099–103,568,978, 2 genes, copy number 8: PTMAP15, AC007751.1.
- chr12:68,808,177–69,855,363, 29 genes, copy number 125 (within-gene range 2–125): MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2.
- chr16:6,380,476–6,395,578, 1 gene, copy number 20: AC006112.1.
- chr16:11,196,177–11,527,245, 17 genes, copy number 16 (within-gene range 3–16): AC007220.1, HNRNPCP4, RMI2, SOCS1, TNP2, PRM3, AC009121.1, PRM2, PRM1, AC009121.4, MIR548H2, Y_RNA, AC009121.3, AC009121.2, AC099489.1, AC099489.2, AC099489.3.
- chr16:13,728,654–13,779,760, 1 gene, copy number 19: U95743.1.
- chr16:15,643,267–15,734,691, 1 gene, copy number 8 (within-gene range 3–8): NDE1.
- chr16:15,683,290–15,932,294, 10 genes, copy number 8: AC026401.2, AC026401.3, MYH11, AF001548.2, AF001548.1, AF001548.3, CEP20, RNU6-213P, AC130651.1, RPL15P20.
- chr18:8,609,437–8,707,621, 4 genes, copy number 8: RAB12, AP001793.1, TOMM20P3, GACAT2.
- chr18:8,720,034–8,720,132, 1 gene, copy number 8: Y_RNA.
- chr20:55,074,644–56,786,087, 30 genes, copy number 7–9: RPL12P4, LINC01440, LINC01441, AL160413.1, AL109829.1, AL109828.1, CBLN4, RNA5SP487, MC3R, AL139824.2, AL139824.1, FAM210B, AURKA, CSTF1, CASS4, RPL39P, RTF2, GCNT7, FAM209A, AL109806.1, FAM209B, AL109806.2, LINC01716, RPS4XP3, TFAP2C, RNU6-1146P, RN7SL170P, PTMAP6, AL133232.1, RNU6-929P.
- chr20:62,550,453–64,313,132, 112 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,701. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
